TCGA case TCGA-62-A46U — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Thoraxklinik at University Hospital Heidelberg. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/793649e5-f479-4d64-8723-2ef488fe0fd9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma with mixed subtypes: ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 71.2 years (25,998 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Vinorelbine Tartrate; Days to treatment start: 71 days; Days to treatment end: 161 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,708 days (4.7 years); Disease response: Tumor Free.
- Days to follow up: 2,067 days (5.7 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; Timepoint: Preoperative.

Other clinical attributes
- FEV1/FVC before bronchodilator (%): 81; FEV1 before bronchodilator (% of reference): 131.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-62-A46U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-62-A46U-01A-01-TS1: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-62-A46U-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-62-A46U-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Anatomic organ subdivision: R-Lower; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Navelbine.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,067 days; disease-specific survival: no event (censored), 2,067 days; disease-free interval: no event (censored), 2,067 days; progression-free interval: no event (censored), 2,067 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-62-A46U-01A-11D-A24C-01): tumor purity 0.25, ploidy 3.73, whole-genome doublings 1.
